Gene-level copy-number profile of specimen HCM-BROD-0134-C25-85A from HCMI case HCM-BROD-0134-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 63.0 years (22,999 days).
Specimen HCM-BROD-0134-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 248a2c6d-7f33-4b60-95ee-e5cd23abfe38.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0134-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,723 have no estimate.
https://portal.gdc.cancer.gov/files/940005af-deb5-422f-8a85-65bf2a2ba988

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 63; copy number 1: 3,235; copy number 2: 21,040; copy number 3: 24,607; copy number 4: 7,577; copy number 5: 2,206; copy number 6: 149; copy number 7: 12; copy number 9: 1; copy number 17: 10.

Homozygous deletions (total copy number 0; autosomes only): 63 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,638,285–27,610,745, 63 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 23 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:35,147,410–35,149,184, 1 gene, copy number 9: AL353795.1.
- chr19:33,555,568–34,229,515, 12 genes, copy number 7: AC010485.1, RPL21P131, CHST8, KCTD15, AC008556.1, RN7SL150P, AC016587.1, RPS4XP23, RPS4XP20, RPS4XP21, CHCHD2P3, LSM14A.
- chr20:11,234,170–11,926,609, 10 genes, copy number 17: AL049649.1, RPS11P1, AL109837.1, PGAM3P, AL161938.1, LINC00687, RN7SKP111, AL080274.1, BTBD3, AL035448.1.

Autosomal genes at a single copy (total copy number 1): 1,848. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
